Somatic mutation profile of tumor specimen TCGA-49-4494-01A (aliquot TCGA-49-4494-01A-01D-1265-08) from TCGA case TCGA-49-4494, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 77.7 years (28,387 days).
Specimen TCGA-49-4494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ebd8976-aa26-491e-8406-86574f6cd76a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4494-11A (Solid Tissue Normal), aliquot TCGA-49-4494-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88dd94aa-b147-44d9-9a20-f5ee3e0e99c8

The open-access MAF lists 203 somatic variants for this specimen: 149 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 47, Nonsense Mutation 9, Splice Site 5, Intron 4, Frame Shift Del 3, 5'Flank 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 98/193 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434569, CM054664, COSV51765492; ClinVar: drug response / likely pathogenic / pathogenic / protective; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 101/223 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- SNRPD3 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV53182727, COSV53183815, COSV99307458; called by muse, mutect2, varscan2
- ABCA7 | c.1552C>A p.L518I | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.254); catalogued as COSV54036435; called by muse, mutect2, varscan2
- ABCB5 | c.2918T>A p.V973D (on ENST00000404938 / NM_001163941.2; = p.V528D on NM_178559.6) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV51719037; called by muse, mutect2, varscan2
- ABCC9 | c.2494A>G p.I832V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV53983699; called by muse, mutect2, varscan2
- ADAM22 | c.1681+2T>G p.X561_splice | Splice Site (SNP) | VAF 19/126 reads (15%) | catalogued as COSV55988264; called by muse, mutect2, varscan2
- ADGRE2 | c.2170C>T p.L724F | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV59695997; called by muse, mutect2, varscan2
- ADGRL4 | c.1886C>T p.T629I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100875958, COSV66065106; called by muse, mutect2, varscan2
- ADH7 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52922416, COSV52922927; called by muse, mutect2, varscan2
- AGO2 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV55052069; called by muse, mutect2, varscan2
- ATRIP | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as COSV56497958; called by muse, mutect2, varscan2
- C10orf53 | c.234T>A p.S78R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV65109495; called by muse, mutect2, varscan2
- C14orf28 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV57333288; called by muse, mutect2
- CACNA1E | c.5184C>A p.Y1728* | Nonsense Mutation (SNP) | VAF 37/278 reads (13%) | catalogued as COSV100703236, COSV62414973; called by muse, mutect2, varscan2
- CATSPERB | c.2632G>T p.A878S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.457); catalogued as COSV56433549; called by muse, mutect2, varscan2
- CCDC106 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.156); catalogued as COSV54402568; called by muse, mutect2, varscan2
- CCDC33 | c.320-1G>C p.X107_splice | Splice Site (SNP) | VAF 39/191 reads (20%) | catalogued as COSV100351914; called by muse, mutect2, varscan2
- CCT8L2 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as COSV63463648, COSV63463841; called by muse, mutect2
- CD1A | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56862312, COSV56863993; called by muse, mutect2, varscan2
- CDH8 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV54895096; called by muse, mutect2, varscan2
- CELF5 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs751027249, COSV53014692; called by muse, mutect2, varscan2
- CFAP47 | c.2642G>T p.C881F | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV52890712; called by muse, mutect2, varscan2
- CHRNA1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 28/146 reads (19%) | catalogued as COSV53684884; called by muse, varscan2
- CILP2 | c.1997C>A p.A666D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99365251; called by muse, mutect2, varscan2
- COL11A1 | c.4693G>T p.A1565S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.057); catalogued as COSV62195058; called by muse, mutect2, varscan2
- CPA2 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV55981188; called by muse, mutect2, varscan2
- CPS1 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.782); catalogued as COSV51822380; called by muse, mutect2, varscan2
- CRB1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.322); catalogued as COSV66333035; called by muse, mutect2, varscan2
- CRTC1 | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58722814; called by muse, mutect2, varscan2
- CSMD1 | c.7427G>C p.R2476P (on ENST00000520002; = p.R2475P on NM_033225.6) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as rs746088122, COSV59327160, COSV59373995; called by muse, varscan2
- CWC27 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66888399; called by muse, mutect2
- DACH1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57516881; called by muse, mutect2, varscan2
- DCAF12L2 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV63583931; called by muse, varscan2
- DCAF4L2 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV60481826; called by muse, mutect2, varscan2
- DNAH9 | c.4252G>T p.D1418Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52361497, COSV52372685; called by muse, mutect2, varscan2
- DYNC2H1 | c.4268G>A p.R1423H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771893039, COSV62104833; called by muse, mutect2
- EPHA6 | c.629G>T p.W210L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV67591181; called by muse, mutect2, varscan2
- EXTL3 | c.2461A>G p.I821V | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.858); catalogued as COSV55040159; called by muse, mutect2, varscan2
- FGF14 | c.737C>A p.T246K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV65955591; called by muse, mutect2, varscan2
- FKBP6 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52722674; called by muse, mutect2, varscan2
- FMN2 | c.3397C>A p.P1133T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as COSV100144171, COSV60450071; called by muse, varscan2
- FOLH1 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924027; called by muse, mutect2, varscan2
- GABRA5 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59485184; called by muse, mutect2, varscan2
- GAN | c.1612+1G>C p.X538_splice | Splice Site (SNP) | VAF 41/319 reads (13%) | catalogued as rs1567501269, COSV73721302; called by muse, mutect2, varscan2
- GIMAP8 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV56233425; called by muse, mutect2, varscan2
- GLRA4 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV65456865; called by muse, mutect2, varscan2
- HERC2 | c.6553G>T p.G2185W | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV55346168; called by muse, mutect2, varscan2
- HPS4 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV61105245; called by muse, mutect2, varscan2
- HTR1A | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60502668; called by muse, mutect2, varscan2
- ICA1L | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64174792; called by muse, mutect2, varscan2
- INSL6 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101068488, COSV101068545; called by muse, mutect2, varscan2
- KCNA4 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | catalogued as COSV60251905; called by muse, mutect2, varscan2
- KCNB2 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV101578769, COSV73052577; called by muse, mutect2, varscan2
- KIF13A | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52447008, COSV52463401; called by muse, mutect2, varscan2
- KRTAP10-4 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs781877092, COSV59977628; called by muse, mutect2, varscan2
- LARP1 | c.2106C>G p.I702M (on ENST00000518297 / NM_033551.3; = p.I625M on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as COSV60430735; called by muse, mutect2
- LCLAT1 | c.1059G>C p.W353C | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58377694; called by muse, mutect2, varscan2
- LCT | c.3599C>G p.T1200R | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51550301, COSV51556422; called by muse, mutect2, varscan2
- LPA | c.77A>C p.Q26P | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV60310073; called by muse, mutect2, varscan2
- LRP1B | c.2552G>C p.R851P | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.53); catalogued as COSV63341975; called by muse, mutect2, varscan2
- LRPPRC | c.470-1G>T p.X157_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV53242558; called by muse, mutect2, varscan2
- LRRK1 | c.4714A>T p.M1572L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52624590; called by muse, mutect2, varscan2
- LSM14A | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs1205177052, COSV101471761; called by muse, mutect2, varscan2
- MED12L | c.5762C>A p.P1921H | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as COSV56394197, COSV56396917; called by muse, mutect2, varscan2
- MED13L | c.5696G>T p.G1899V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56116694; called by muse, mutect2, varscan2
- MGA | c.6343G>T p.E2115* (on ENST00000219905 / NM_001164273.1; = p.E1906* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54961690; called by muse, mutect2, varscan2
- MICAL3 | c.3606G>T p.L1202F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV71588851; called by muse, mutect2, varscan2
- MLX | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV53818722; called by muse, mutect2, varscan2
- MTERF3 | c.187A>T p.T63S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV54634294; called by muse, mutect2, varscan2
- MUC16 | c.10772C>A p.S3591Y | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV67488870, COSV67492576; called by muse, mutect2, varscan2
- MUC16 | c.9773G>T p.S3258I | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV67488875; called by muse, mutect2, varscan2
- MUC16 | c.7874C>A p.P2625Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV101201928; called by muse, mutect2
- MUC17 | c.2825G>C p.R942T | Missense Mutation (SNP) | VAF 32/684 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60301044; called by muse, mutect2
- MYH4 | c.3738G>T p.K1246N | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55124822; called by muse, varscan2
- N4BP2L2 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99912734; called by muse, mutect2
- NFAT5 | c.2525G>T p.S842I | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs1480795839, COSV63032007; called by muse, mutect2, varscan2
- NLRP14 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV55071310; called by muse, mutect2, varscan2
- NPAP1 | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as COSV61505391, COSV61510583; called by muse, mutect2, varscan2
- NTRK1 | c.1930C>A p.L644M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV62323372; called by muse, mutect2, varscan2
- OBSCN | c.23389A>G p.M7797V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs755708853, COSV63280819; called by muse, mutect2, varscan2
- OR10H1 | c.801G>T p.Q267H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58472776; called by muse, mutect2, varscan2
- OR4D6 | c.626T>A p.L209H | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1313532232, COSV55660879; called by muse, mutect2, varscan2
- OR4N2 | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV60054444, COSV60054920; called by muse, mutect2, varscan2
- OR5D16 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65721457; called by muse, mutect2, varscan2
- ORC4 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV51576642; called by muse, mutect2, varscan2
- ORC5 | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs565090474, COSV99857471; called by muse, mutect2, varscan2
- PCDHGA1 | c.1714T>A p.S572T | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV65299004; called by muse, mutect2, varscan2
- PCDHGB5 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54017974; called by muse, mutect2, varscan2
- PCNX2 | c.2721A>T p.R907S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50867821; called by muse, mutect2, varscan2
- PCOLCE2 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 29/213 reads (14%) | catalogued as COSV56001661; called by muse, mutect2, varscan2
- PHF24 | c.961C>A p.H321N | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54276501; called by muse, mutect2, varscan2
- PLEKHA6 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1225295333, COSV55332524; called by muse, mutect2, varscan2
- POTEE | c.2317C>G p.H773D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100389144; called by muse, mutect2, varscan2
- PPIP5K2 | c.3238G>T p.D1080Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV58609057; called by muse, mutect2, varscan2
- PRKAG2 | c.650T>A p.L217Q | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV55224922, COSV55239102; called by muse, mutect2, varscan2
- PRKCA | c.1796G>T p.R599M | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV101151269; called by muse, mutect2, varscan2
- PRKCA | c.1797G>T p.R599S | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV101151239, COSV101151271; called by muse, mutect2, varscan2
- PROS1 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.298); catalogued as rs941052460, COSV62399501; called by muse, mutect2, varscan2
- PSG3 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV59504503, COSV59506533; called by muse, mutect2, varscan2
- PTPRJ | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69252723, COSV69254236; called by muse, mutect2, varscan2
- RBM10 | c.576+1G>T p.X192_splice | Splice Site (SNP) | VAF 24/51 reads (47%) | catalogued as COSV61311810; called by muse, mutect2, varscan2
- RELN | c.4993C>A p.Q1665K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV59029982; called by muse, mutect2, varscan2
- RETSAT | c.1501G>T p.V501F | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55528542; called by muse, mutect2, varscan2
- RNF165 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV53977288; called by muse, mutect2, varscan2
- RUNDC3B | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV56696450; called by muse, mutect2, varscan2
- RYR2 | c.7690G>T p.A2564S | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV63709570; called by muse, mutect2, varscan2
- SH3RF1 | c.2597G>C p.W866S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52924580; called by muse, mutect2
- SIGLEC12 | c.1753G>A p.G585S (on ENST00000291707 / NM_053003.4; = p.G467S on NM_033329.2) | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as rs1404015707, COSV52464494; called by muse, mutect2, varscan2
- SIGLEC9 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51587606; called by muse, mutect2, varscan2
- SLIT1 | c.2308G>T p.G770W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99822671; called by muse, mutect2
- SOX5 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV58645964; called by muse, mutect2, varscan2
- SPEM2 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1193778247, COSV61604528; called by muse, mutect2, varscan2
- SSTR3 | c.1072G>T p.G358W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV60730234; called by muse, mutect2, varscan2
- TCEAL2 | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV100216416; called by muse, mutect2, varscan2
- TECRL | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1192008303, COSV67090058; called by muse, mutect2, varscan2
- TEX15 | c.3050T>A p.L1017H (on ENST00000256246; = p.L1400H on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56352517; called by muse, mutect2, varscan2
- THADA | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs574838357, COSV57691697; called by muse, mutect2, varscan2
- TLR9 | c.1019A>C p.N340T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); catalogued as COSV62348261; called by muse, mutect2, varscan2
- TMIGD2 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56667562, COSV56668501; called by muse, mutect2, varscan2
- TMPRSS15 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV53040359, COSV53047639; called by muse, mutect2, varscan2
- TNKS2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV65416773; called by muse, mutect2, varscan2
- TOR1AIP2 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV62627045; called by muse, mutect2, varscan2
- TRIM27 | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65874022; called by muse, mutect2, varscan2
- TRIM65 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99485618; called by muse, mutect2, varscan2
- TSG101 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52650445, COSV99324306; called by muse, mutect2, varscan2
- TTN | c.2486G>C p.G829A (on ENST00000591111; = p.G783A on NM_003319.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | PolyPhen benign (0.078); catalogued as COSV100636356, COSV60298022; called by muse, mutect2, varscan2
- UBR7 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 30/169 reads (18%) | catalogued as COSV50150996; called by muse, mutect2, varscan2
- UGGT2 | c.3589G>T p.D1197Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100948813, COSV65078655; called by muse, mutect2, varscan2
- UNC13D | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411588113, COSV52886984; called by muse, mutect2, varscan2
- UNC5B | c.2375G>C p.C792S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58977680, COSV58980769; called by muse, mutect2, varscan2
- URGCP | c.2017C>T p.R673C (on ENST00000453200 / NM_001077663.3; = p.R664C on NM_017920.4) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs530387888, COSV56252019; called by muse, mutect2, varscan2
- USH1C | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50032641; called by muse, mutect2, varscan2
- USH2A | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100243357; called by muse, mutect2
- VEGFC | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 156/391 reads (40%) | catalogued as rs1452319332, COSV54598261; called by muse, mutect2, varscan2
- VPS50 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59922437; called by muse, mutect2
- WNT5B | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 37/170 reads (22%) | catalogued as rs972730694, COSV60198878; called by muse, mutect2, varscan2
- ZFP14 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99525367; called by muse, mutect2, varscan2
- ZNF423 | c.1707G>C p.E569D (on ENST00000563137 / NM_001379286.1; = p.E561D on NM_015069.4) | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.856); catalogued as COSV52202158; called by muse, mutect2, varscan2
- ZNF454 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as COSV60770130; called by muse, mutect2, varscan2
- ZNF521 | c.61del p.D21Tfs*9 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | catalogued as COSV64123657; called by mutect2, pindel, varscan2
- ZNF680 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV59017674; called by mutect2, varscan2
- ZNF778 | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60601382, COSV60602675; called by muse, mutect2, varscan2
- ZNF804B | c.3253G>T p.V1085L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV60850307; called by muse, mutect2, varscan2
- GZMK | c.18del p.S8Lfs*5 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- IGHM | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- MAGEB6B | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- MYO19 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NECTIN4 | c.134del p.G45Afs*35 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- A2ML1 | c.390C>G p.L130= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV55297361; called by muse, mutect2, varscan2
- ACTRT2 | c.987C>A p.I329= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV65760344; called by muse, mutect2, varscan2
- AGAP6 | c.993C>T p.P331= (on ENST00000374056 / NM_001365867.1; = p.P354= on NM_001077665.2) | Silent (SNP) | VAF 52/409 reads (13%) | called by muse, mutect2, varscan2
- ATP8B4 | c.1113T>A p.P371= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV52722952; called by muse, mutect2, varscan2
- BMPER | c.1197G>A p.S399= | Silent (SNP) | VAF 43/324 reads (13%) | catalogued as rs1420233725, COSV51822468, COSV51826062; called by muse, mutect2, varscan2
- BTNL2 | c.693G>T p.S231= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV66631790; called by muse, mutect2, varscan2
- CADM3 | c.1071G>A p.R357= (on ENST00000368125 / NM_001127173.3; = p.R391= on NM_021189.5) | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1305560909, COSV63676394; called by muse, mutect2
- CASR | c.1611C>T p.I537= (on ENST00000490131; = p.I614= on NM_000388.4) | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs199513106, COSV56134645; called by muse, mutect2, varscan2
- CLASP2 | c.3222C>T p.T1074= (on ENST00000359576; = p.T1073= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1367066185, COSV56292240; called by muse, mutect2, varscan2
- CPT1B | c.924G>A p.Q308= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV56418675; called by muse, mutect2, varscan2
- CYP24A1 | c.831C>A p.T277= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs368898455, COSV53776382; called by muse, mutect2, varscan2
- DNTTIP2 | c.1296C>T p.N432= | Silent (SNP) | VAF 49/242 reads (20%) | catalogued as COSV63284523; called by muse, mutect2, varscan2
- EML3 | c.1749A>G p.G583= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV53874426; called by muse, mutect2, varscan2
- F2R | c.354A>T p.P118= | Silent (SNP) | VAF 48/257 reads (19%) | catalogued as COSV100058702, COSV59929262; called by muse, mutect2, varscan2
- HAS3 | c.1149A>T p.S383= | Silent (SNP) | VAF 60/194 reads (31%) | catalogued as COSV54708969; called by muse, mutect2, varscan2
- KAT6A | c.4356G>T p.A1452= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV55911217, COSV99704620; called by muse, mutect2, varscan2
- KCNA4 | c.1122G>T p.V374= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100069313; called by muse, mutect2, varscan2
- KCNJ4 | c.1227G>A p.E409= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV57858535; called by muse, mutect2, varscan2
- KRT79 | c.1476G>T p.G492= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV57941948, COSV57942390; called by muse, mutect2, varscan2
- MRM1 | c.972A>G p.Q324= | Silent (SNP) | VAF 62/295 reads (21%) | catalogued as rs367759770; called by muse, mutect2, varscan2
- NAV2 | c.474A>T p.A158= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV62333049; called by muse, mutect2, varscan2
- NCBP3 | c.1131C>G p.L377= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV99339734; called by muse, mutect2, varscan2
- NGEF | c.726C>T p.L242= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV50948608; called by muse, mutect2
- NTS | c.66G>T p.L22= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99755224; called by muse, mutect2, varscan2
- NYAP1 | c.1569G>T p.G523= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100278722; called by muse, mutect2, varscan2
- OR4K15 | c.111G>T p.V37= (on ENST00000305051; = p.V13= on NM_001005486.1) | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV59303161; called by muse, mutect2, varscan2
- OR5B3 | c.849G>T p.L283= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV58678498; called by muse, mutect2
- PCDHA3 | c.1863G>A p.P621= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs782445556, COSV63540643; called by muse, mutect2, varscan2
- PCDHB4 | c.1635G>A p.L545= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV52026307; called by muse, mutect2
- PRAMEF10 | c.1170C>A p.S390= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- PTGDR | c.483G>T p.L161= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as COSV60094908; called by muse, mutect2, varscan2
- RARG | c.1032G>A p.L344= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV58434486; called by muse, mutect2, varscan2
- RELN | c.7809C>A p.G2603= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV59029973; called by muse, mutect2, varscan2
- RHBDL3 | c.189G>A p.L63= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99283994; called by muse, mutect2, varscan2
- RTN2 | c.1092G>A p.L364= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV55595795; called by muse, mutect2, varscan2
- SCGB2A2 | c.12G>T p.L4= | Silent (SNP) | VAF 52/285 reads (18%) | catalogued as COSV99929376; called by muse, mutect2, varscan2
- SENP7 | c.2814A>T p.L938= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV58617715; called by muse, mutect2, varscan2
- SLC17A2 | c.321C>A p.I107= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs756728488, COSV55354585; called by muse, varscan2
- SLC5A5 | c.1278C>T p.P426= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV55835200; called by muse, mutect2, varscan2
- SPIN2A | c.561C>G p.R187= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100888071; called by muse, mutect2, varscan2
- TAF4 | c.2628G>T p.A876= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as COSV53342141; called by muse, mutect2, varscan2
- TRIM67 | c.2148G>A p.G716= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as COSV64160222; called by muse, mutect2, varscan2
- TSG101 | c.1068G>C p.L356= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99324308; called by muse, mutect2, varscan2
- TSPYL2 | c.1296A>C p.A432= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV64921453; called by muse, mutect2, varscan2
- ZNF418 | c.348G>A p.G116= | Silent (SNP) | VAF 17/223 reads (8%) | catalogued as COSV101269028; called by muse, mutect2
- ZNF536 | c.2220G>T p.L740= | Silent (SNP) | VAF 59/248 reads (24%) | catalogued as COSV62832879; called by muse, mutect2, varscan2
- ZNF592 | c.1707G>A p.A569= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as rs376399381; called by muse, varscan2
- AP000769.3 | chr11:65504791 C>T | 5'Flank (SNP) | VAF 14/80 reads (18%) | catalogued as rs1460139726; called by muse, mutect2, varscan2
- EYA2 | c.-10-11370G>T | Intron (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100564893; called by muse, mutect2, varscan2
- MRE11 | c.1098+1243G>A | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as rs1050212546; called by muse, mutect2
- SNORD116-14 | chr15:25082860 A>T | 3'Flank (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- USH1C | c.1285-3910T>A | Intron (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99142287; called by muse, mutect2, varscan2
- XIST | n.7933C>A | RNA (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- ZNF665 | c.-53-9223G>T | Intron (SNP) | VAF 26/138 reads (19%) | catalogued as COSV67217188; called by muse, mutect2, varscan2
